Gene-level copy-number profile of tumor specimen TCGA-55-8301-01A from TCGA case TCGA-55-8301, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.0 years (21,535 days).
Specimen TCGA-55-8301-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.11bee791-e550-4d61-b424-47eed700529f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8301-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10167db2-eecb-4132-bb8d-2d42318cd179

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 81; copy number 1: 42,759; copy number 2: 12,969; copy number 3: 2,913; copy number 4: 496; copy number 5: 485; copy number 6: 24; copy number 8: 53; copy number 9: 10; copy number 11: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8301-01A-11D-2283-01): tumor purity 0.26, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,005 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 3 (broad region; genes not listed).
- chr5:58,198–39,103,677, 608 genes, copy number 4–5 (broad region; genes not listed).
- chr8:57,126,655–60,623,644, 47 genes, copy number 3 (within-gene range 2–3): RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3.
- chr8:67,732,587–70,078,032, 33 genes, copy number 3: AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P.
- chr8:81,149,107–85,540,511, 60 genes, copy number 3–4: AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1.
- chr8:127,578,473–145,066,685, 334 genes, copy number 4–5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:27,258,717–39,388,513, 205 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr19:27,638,483–33,175,799, 113 genes, copy number 5–11 (broad region; genes not listed).
- chr19:33,178,056–33,178,651, 1 gene, copy number 5: AC008738.1.

Autosomal genes at a single copy (total copy number 1): 40,419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
